Somatic mutation profile of tumor specimen TCGA-G7-A8LC-01A (aliquot TCGA-G7-A8LC-01A-11D-A35Z-10) from TCGA case TCGA-G7-A8LC, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.7 years (22,553 days).
Specimen TCGA-G7-A8LC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67f5cfb6-ec03-4240-b1a7-e2262ee7e9db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-A8LC-10A (Blood Derived Normal), aliquot TCGA-G7-A8LC-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26a793eb-ebd9-4fd1-ba1c-5a932c87b6fe

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGPAT1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100421700; called by muse, mutect2
- POLR1A | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99808277; called by muse, mutect2
- PRAG1 | c.723G>T p.R241S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV100422688; called by muse, mutect2
- SLC25A34 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV99606770; called by muse, mutect2
- SWT1 | c.1485C>G p.H495Q | Missense Mutation (SNP) | VAF 56/79 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100833497; called by muse, mutect2, varscan2
- TOMM40 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.041); catalogued as rs1227783364, COSV99376245; called by muse, mutect2, varscan2
- TRAPPC9 | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 143/190 reads (75%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs748083795, COSV101228419; called by muse, mutect2, varscan2
- YLPM1 | c.4922A>T p.D1641V | Missense Mutation (SNP) | VAF 78/126 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99461064; called by muse, mutect2, varscan2
- ZC3H12A | c.1109A>T p.E370V | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100897761; called by muse, mutect2, varscan2
- SAV1 | c.463_465delinsTA p.D155Yfs*34 | Frame Shift Del (DEL) | VAF 125/394 reads (32%) | called by pindel, varscan2*
- SLC26A5 | c.1902C>T p.P634= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100099984; called by muse, mutect2
- SLC6A3 | c.918C>T p.C306= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs746199611, COSV54366997; called by muse, mutect2, varscan2
- NACA | c.71-2244T>C | Intron (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100771575; called by muse, mutect2, varscan2
- PDGFD | c.125-36588G>A | Intron (SNP) | VAF 44/105 reads (42%) | catalogued as rs777102812, COSV56395204; called by muse, mutect2, varscan2
